Gene-level copy-number profile of tumor specimen TCGA-CV-7425-01A from TCGA case TCGA-CV-7425, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 77.7 years (28,368 days).
Specimen TCGA-CV-7425-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.29efcc27-a1b3-485d-ae13-6a75906a1426.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7425-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8caa5c4d-f692-4bb2-af7b-1e153a76f9f4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 13; copy number 2: 1,047; copy number 3: 1,168; copy number 4: 41,784; copy number 5: 15,165; copy number 6: 32; copy number 7: 78; copy number 10: 1; copy number 18: 277; copy number 22: 145; copy number 23: 105.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7425-01A-11D-2077-01): tumor purity 0.49, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 528 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–10,612,723, 145 genes, copy number 22 (within-gene range 4–23) (broad region; genes not listed).
- chr9:9,799,423–19,786,928, 106 genes, copy number 10–23 (broad region; genes not listed).
- chr9:34,638,133–43,045,120, 277 genes, copy number 18 (within-gene range 3–18) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
